Surgical pathology report (de-identified scan), TCGA case TCGA-CX-A4AQ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Medical College of Georgia, specimen TCGA-CX-A4AQ-01A (Primary Tumor).

[page 1 of 5]
**Surgical Final Report
Temporary Copy**

Page 1 of 5

Case:
Collected:
Ordered by:

Patient: [REDACTED]
ID: [REDACTED]
Location:

Final Pathologic Diagnosis

A) LEVEL II, RIGHT NECK (DISSECTION):

- Fibroadipose tissue, negative for tumor.

B) LEVEL IIB, RIGHT NECK (DISSECTION):

- One lymph node, negative for tumor (0/1).

C) LEVEL III, RIGHT NECK (DISSECTION):

- Fibroadipose tissue, negative for tumor.

D) SELECTIVE NECK DISSECTION, RIGHT (DISSECTION):

- Metastatic squamous cell carcinoma involving two of forty lymph nodes (2/40).
- Salivary gland with chronic inflammation, negative for tumor.

E) DEEP MARGIN (BIOPSY):

- Skeletal muscle, negative for tumor.

F) MEDIAL MARGIN (BIOPSY):

- Squamous mucosa, negative for tumor.

G) LATERAL MARGIN (BIOPSY):

- Squamous mucosa, negative for tumor.

H) ANTERIOR MARGIN (BIOPSY):

- Squamous mucosa, negative for tumor.

I) RIGHT FLOOR OF MOUTH (RESECTION):

- Poorly differentiated squamous cell carcinoma with basaloid features (see synoptic report).
- Anterior, deep and posterior resection margins are positive for tumor.

TNM Stage: pT2 N2b Mx

J) ANTERIOR MARGIN OF MANDIBLE (RESECTION):

- Bone, negative for tumor.

SYNOPTIC REPORT

MACROSCOPIC

Specimen Type

ICD-0.3
LACF: Carcinoma, squamous cell, NOS 8070/3
Path: Carcinoma, basaloid 8083/3
Site: Mouth, floor, NOS C04.9

hw
9/29/12

hw
9/10/12

[page 2 of 5]
Surgical Final Report

Temporary Copy

Case:

Collected:

Ordered by:

Page 2 of 5

Patient:

ID:

Location: I

Resection (specify type): Marginal Mandibulectomy
Tumor Site: Oral cavity

Tumor Size

Greatest dimension: 2.4 cm

*Additional dimensions: 2.3 x 1.0 cm

MICROSCOPIC

Histologic Type

Carcinomas of the Upper Aerodigestive Tract
Basaloid squamous cell carcinoma

Histologic Grade

G3: Poorly differentiated

Pathologic Staging (pTNM) (see appropriate site below)

Primary Tumor (pT): Lip and Oral Cavity

pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension

Regional Lymph Nodes (pN): All Aerodigestive Sites Except Nasopharynx

pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension

Specify: Number examined: 41

Number involved: 2 [One lymph node is at level I (measures 4cm) and the other is at level III (measures 1.4cm)].

Distant Metastasis (pM)

pMX: Cannot be assessed

Margins (check all that apply)

Carcinoma in situ is identified but does not involve a margin.

Margin(s) involved by tumor

Specify margin(s), if possible: Anterior, deep and posterior.

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L)

Present

Perineural Invasion

Absent

Additional Pathologic Findings

Carcinoma in situ

Comment(s)

[page 3 of 5]
Surgical Final Report
Temporary Copy

Case:
Collected:
Ordered by:

Page 3 of 5

Patient:
ID:
Location:

I attest I have personally reviewed the specimen/slides and agree with the above findings.

Electronic Signature
Verified:

Resident:

Intraoperative Diagnosis

FS E1: Negative.
FS F1: Negative.
FS G1: Negative.
FS H1: Negative.

Clinical History

y/o male with T₁N₂A_{M0} SCCA right floor of mouth with adherence to mandibular periosteum.

Pre/Post-operative Diagnosis

T₁N₂A_{M0} of floor mouth.

Gross Anatomic Description

(Dictated by _____ or _____ ; Reviewed by _____)

Specimens received in ten containers.

Specimen A: Designated "right neck level II" is received in formalin labeled with the patient's name and "right neck level II". Specimen consists of a fragment of yellow/ tan lobulated fibrofatty tissue measuring 2 x 1.5 x 0.2 cm.

Section code: A1 – single cassette, entire specimen bisected.

Specimen B: Designated "right neck level IIB" is received in formalin labeled with the patient's name and "right neck level IIB". Specimen consists of a fragment of yellow/ tan lobulated fibrofatty tissue measuring 3.5 x 1.5 x 0.2 cm.

Section code: B1-B2 – entire specimen.

Specimen C: Designated "right neck level III" is received in formalin labeled with the patient's name, MRN and "right neck level III". Specimen consists of a single fragment of yellow/ tan lobulated fibrofatty tissue measuring 2.5 x 1.3 x 0.2 cm.

Section code: C1-C2 – single cassette, entire specimen.

Specimen D: Designated "right selective neck dissection, short stitch level I/ long stitch level IV" is received fresh for Tumor Bank labeled with the patient's name and "right selective neck dissection, short stitch level I/ long stitch level IV". Specimen consists of a 15 x 6.5 x 2.5 cm right neck dissection consisting of sternocleidomastoid muscle, and lymph node levels 1-IV. The specimen is oriented by suture (short = level I, long = level IV). The submandibular gland is not identified grossly.

[page 4 of 5]
Surgical Final Report Temporary Copy

Case:
Collected:
Ordered by:

Page 4 of 5

Patient: [REDACTED]
ID: [REDACTED]
Location:

The sternocleidomastoid muscle (7.5 x 4 x 1.8 cm) is red/ brown and adherent to adjacent lymph nodes. The entire jugular vein (8 cm in length, 0.3 cm in diameter) has a smooth inner lining and is grossly uninvolved by tumor. Level one contains a 4 x 2.2 x 1.5 cm lymph node. Measurements for the lymph node – containing soft levels, are as follows: Level I = 8 x 6.0 x 2.5 cm. Level II = 6.5 x 3 x 1.5 cm. Level III = 7 x 3 x 1.5 cm and level IV = 6 x 3 x 1.5, and level V = 2.0 x 2.0 x 1.5 cm. No nodes are identified in level 2.

Section code: D1-D2 – Representative sections of largest node in level 1; D3 – sternocleidomastoid muscle; D4 – internal jugular vein from level III area; D5-D8 remainder of suspected nodes from level I; D5 – bisected; D6 – bisected; D7 – bisected D8 – two suspected nodes; D9-D14 – suspected nodes from level 3, D9 (one node bisected); D10 – one node trisected; D11 – two suspected nodes; D12 – three suspected nodes; D13 – three suspected nodes; D14 – four suspected nodes; D15-D19 – level IV nodes, D15 (bisected); D2-D21 – level V nodes.

Specimen E: Designated "deep margin" is received fresh for intraoperative consultation and frozen section on [REDACTED] and reported at [REDACTED] labeled with the patient's name and "deep margin". Specimen consists of one fragment of red/ tan soft tissue measuring 0.5 x 0.3 x 0.2 cm. The specimen is entirely frozen.
Section code: E1 – frozen section control.

Specimen F: Designated "medial margin" is received fresh for intraoperative consultation and frozen section on [REDACTED] and reported at [REDACTED] labeled with the patient's name and "medial margin". Specimen consists of one fragment of red/ tan soft tissue measuring 0.7 x 0.4 x 0.3 cm. The specimen is entirely frozen.
Section code: F1 – frozen section control.

Specimen G: Designated "lateral margin" is received fresh for intraoperative consultation and frozen section on [REDACTED] and reported at [REDACTED] labeled with the patient's name and "lateral margin". Specimen consists of one fragment of red/ tan soft tissue measuring 2.2 x 0.2 x 0.2 cm. The specimen is entirely frozen.
Section code: G1 – frozen section control.

Specimen H: Designated "anterior margin" is received fresh for intraoperative consultation and frozen section on [REDACTED] at [REDACTED] and reported at [REDACTED] labeled with the patient's name and "anterior margin". Specimen consists of one fragment of red/ tan soft tissue measuring 1.0 x 0.1 x 0.1 cm. The specimen is entirely frozen.
Section code: H1 – single cassette, frozen section control.

Specimen I: Designated "right floor of mouth, short stitch equals anterior/ long stitch equals posterior" is received in formalin labeled with the patient's name and "right floor of mouth, short stitch equals anterior/ long stitch equals posterior". Specimen consists of a red/ brown fragment of soft tissue measuring 4.5 x 2.5 x 2.0 cm. There is a stitch to indicate the anterior portion and a long stitch to indicate the posterior portion. On the superior/anterior aspect of the specimen, there is a gray/ tan membranous fragment of tissue that measures 3. x 1.6 x 0.2 cm. Cut surface reveals a white/ tan centrally located mass that measures 2.3 x 1 x 2.4 cm. The mass is 2.2 cm from the medial margin, 0.8 cm from the lateral margin and abuts the anterior and posterior margins as well as deep and mucosal margins. Specimen is serially sectioned.
Inking code: Green – anterior; Black – posterior; Red – medial; Yellow – lateral; ; Blue – deep.
Section code: I1 – medial margin, perpendicularly sectioned; I2 – lateral margin, perpendicularly sectioned; I4-I7 – remainder of specimen submitted from medial to lateral.

[page 5 of 5]
Surgical Final Report
Temporary Copy

Case:
Collecte:
Ordered by:

Page 5 of 5

Patient: [REDACTED]
ID: [REDACTED]
Location: :

Specimen J: Designated "anterior margin of mandible" is received in formalin labeled with the patient's name, [REDACTED] and "anterior margin of mandible". Specimen consists of a fragment of light tan bone measuring 3 x 0.7 x 0.3 cm.

Section code: J1-J2 - entire specimen, serially sectioned and entirely submitted after decalcification.

Source: NCI Genomic Data Commons file 6cf2dfe5-c619-4fee-af9f-31b227909d4e (TCGA-CX-A4AQ.AAC99A9E-0C1C-492B-98D6-E9FAD0E31122.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).